CCDI case PBBWWF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f2fa9172-f8d0-42c7-afd3-03c9809cbbc9

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 7.8 years (2,841 days).

Biospecimens (3 samples)
- Sample 0DJE35: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJE3D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DJE3J: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
